Somatic mutation profile of tumor specimen TCGA-2G-AAHN-01A (aliquot TCGA-2G-AAHN-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAHN, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 32.9 years (12,028 days).
Specimen TCGA-2G-AAHN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffae36fa-b364-4bcb-ae57-4751caf11c0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAHN-10A (Blood Derived Normal), aliquot TCGA-2G-AAHN-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1a80e38-e005-46af-a3ca-2b3062d97488

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Nonsense Mutation 3, Silent 3, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2464A>T p.N822Y | Missense Mutation (SNP) | VAF 18/80 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM087050, COSV55387376, COSV55389464; called by muse, mutect2, varscan2
- BPIFA1 | c.400C>G p.P134A | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62824168; called by muse, mutect2, varscan2
- AC068580.4 | c.1064C>A p.T355K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BIN2 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 19/188 reads (10%) | called by muse, mutect2, varscan2
- CELF3 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- COBL | c.1945G>C p.D649H | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- COQ8A | c.1160_1162del p.E387del | In Frame Del (DEL) | VAF 16/134 reads (12%) | called by mutect2, pindel, varscan2
- KMT2B | c.2756del p.P919Rfs*67 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel, varscan2
- LRRC66 | c.451A>T p.K151* | Nonsense Mutation (SNP) | VAF 43/150 reads (29%) | called by muse, mutect2, varscan2
- MLLT3 | c.614A>T p.E205V | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- MUC6 | c.1997G>A p.G666D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH15 | c.858A>G p.I286M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- SFPQ | c.1379del p.P460Lfs*53 | Frame Shift Del (DEL) | VAF 38/342 reads (11%) | called by mutect2, pindel, varscan2
- TDRD6 | c.5807G>A p.C1936Y | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WDR7 | c.2348G>A p.S783N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF276 | c.316C>A p.P106T (on ENST00000443381 / NM_001113525.2; = p.P31T on NM_152287.4) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DPF1 | c.394C>T p.L132= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV62792574; called by muse, mutect2, varscan2
- FAM110C | c.756C>T p.S252= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1187839144; called by muse, mutect2, varscan2
- ZSWIM8 | c.4119C>T p.N1373= (on ENST00000605216 / NM_001242487.2; = p.N1378= on NM_015037.3) | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
